Somatic mutation profile of tumor specimen TCGA-EK-A2IP-01A (aliquot TCGA-EK-A2IP-01A-11D-A17W-09) from TCGA case TCGA-EK-A2IP, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 28.3 years (10,347 days).
Specimen TCGA-EK-A2IP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 429506ec-9e3e-47af-8297-b6e9c30dc764.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2IP-10A (Blood Derived Normal), aliquot TCGA-EK-A2IP-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/237ab760-14e2-4b55-8cd3-f02ac876ff6c

The open-access MAF lists 156 somatic variants for this specimen: 98 protein-altering or splice-affecting, 49 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 49, Nonsense Mutation 5, 5'Flank 4, Intron 3, Splice Region 2, Translation Start Site 2, 5'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADORA3 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV53985638; called by muse, mutect2, varscan2
- AKAP4 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV62074279; called by muse, mutect2, varscan2
- ANKRD30A | c.754C>T p.H252Y (on ENST00000611781; = p.H196Y on NM_052997.2) | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100652807; called by muse, varscan2
- APMAP | c.210C>T p.L70= | Splice Region (SNP) | VAF 8/23 reads (35%) | catalogued as COSV54173702; called by muse, mutect2, varscan2
- ARHGEF15 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV62725017; called by muse, mutect2, varscan2
- AUNIP | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV65352802; called by muse, mutect2, varscan2
- B4GALT4 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63295772; called by muse, mutect2, varscan2
- BPIFC | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55912100; called by muse, mutect2, varscan2
- C3 | c.4772G>A p.R1591K | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.922); catalogued as COSV55574352; called by muse, mutect2, varscan2
- CBWD2 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.468); catalogued as COSV99380171; called by muse, mutect2
- CCDC88B | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1467643802, COSV57265864; called by muse, mutect2, varscan2
- CCDC88B | c.2701G>C p.E901Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV57265868, COSV57268800; called by muse, mutect2, varscan2
- CDKN2A | c.150+8G>C | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as COSV58686156; called by muse, mutect2, varscan2
- CEP152 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV57858902; called by muse, mutect2, varscan2
- CFAP53 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs1336444557, COSV101274937; called by muse, mutect2, varscan2
- CGRRF1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53596532; called by muse, mutect2, varscan2
- CPLX1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV58375861; called by muse, mutect2, varscan2
- DUSP10 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV60457468; called by muse, mutect2, varscan2
- EDNRB | c.1207G>C p.D403H (on ENST00000377211 / NM_001201397.1; = p.D313H on NM_000115.5) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57519691, COSV57521863; called by muse, mutect2, varscan2
- EFCAB12 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV58176081; called by muse, mutect2, varscan2
- EVI5 | c.2408G>C p.R803T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.007); catalogued as COSV64826711; called by muse, mutect2, varscan2
- FAM9A | c.468G>C p.L156F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV66813172, COSV66813264; called by muse, mutect2, varscan2
- FAT3 | c.10495C>T p.P3499S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53102935; called by muse, mutect2, varscan2
- FUZ | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV58241283; called by muse, varscan2
- GAD1 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219260245, COSV100713739; called by muse, varscan2
- GMFG | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs779145008, COSV53419190, COSV53419372, COSV99453299; called by muse, mutect2, varscan2
- GUCY2D | c.3119G>C p.R1040P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1162194690, COSV54695983; called by muse, mutect2, varscan2
- HDAC4 | c.2238C>A p.F746L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs753482334, COSV61860486, COSV61869956; called by muse, mutect2
- HSP90B1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV55354988; called by muse, mutect2, varscan2
- ITGA8 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.289); catalogued as COSV65227857; called by muse, mutect2, varscan2
- JPT1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/456 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100506624; called by muse, mutect2
- KDM1A | c.1772G>T p.R591L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV100752299; called by muse, mutect2
- KIDINS220 | c.3777G>A p.M1259I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56752703; called by muse, mutect2, varscan2
- KIF12 | c.538C>T p.P180S (on ENST00000640217; = p.P42S on NM_138424.1) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.17); catalogued as rs1407356866, COSV65117073; called by muse, mutect2, varscan2
- KIF3B | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65227453; called by muse, mutect2, varscan2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2
- KRT1 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99358449; called by muse, mutect2, varscan2
- LAIR2 | c.172T>C p.F58L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56621350; called by muse, mutect2, varscan2
- LONRF1 | c.1449G>C p.M483I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV68036651; called by muse, mutect2, varscan2
- LRP1B | c.10117G>T p.A3373S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as rs770983705, COSV67210726; called by muse, mutect2, varscan2
- MACC1 | c.2344G>C p.E782Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV60542265; called by muse, mutect2, varscan2
- MAGEB2 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs746022879, COSV66780608; called by muse, mutect2, varscan2
- MAP2 | c.4146C>G p.I1382M | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52288891; called by muse, mutect2, varscan2
- MEOX2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as COSV56289367; called by muse, mutect2, varscan2
- MIEF1 | c.1236G>C p.L412F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775912326, COSV57478713; called by muse, mutect2, varscan2
- MS4A10 | c.324G>T p.L108F | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV100382361; called by muse, mutect2
- MTUS2 | c.3286G>A p.E1096K (on ENST00000612955 / NM_001366650.1; = p.E75K on NM_015233.6) | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764911582, COSV60158106, COSV60158302; called by muse, mutect2, varscan2
- MYH3 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 50/113 reads (44%) | catalogued as COSV56863960; called by muse, mutect2, varscan2
- NAA60 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV100692694; called by muse, mutect2, varscan2
- NAA60 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100692828, COSV62654672; called by muse, mutect2, varscan2
- NEB | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.992); catalogued as rs1198081543, COSV51155509; called by muse, mutect2, varscan2
- NELL1 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs1200712849, COSV100121252, COSV54258825; called by muse, mutect2, varscan2
- NFE2L3 | c.1486C>G p.H496D | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV50226322, COSV50227392; called by muse, mutect2, varscan2
- OFD1 | c.1771A>T p.N591Y | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100406696; called by muse, mutect2, varscan2
- OR6C2 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); catalogued as COSV59515933, COSV59516354; called by muse, mutect2, varscan2
- PACS2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs587614619, COSV100330575; called by muse, mutect2
- PAGE1 | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV65998008; called by muse, mutect2, varscan2
- PAX1 | c.1339T>A p.C447S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV68271638; called by muse, mutect2, varscan2
- PCDHA2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV65365226; called by muse, mutect2, varscan2
- PCDHB11 | c.1320G>T p.L440F | Missense Mutation (SNP) | VAF 57/86 reads (66%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.153); catalogued as COSV61311169; called by muse, mutect2, varscan2
- PCLO | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 83/181 reads (46%) | catalogued as COSV100438327, COSV61631221; called by muse, mutect2, varscan2
- PCNX3 | c.5130C>G p.D1710E | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV63136349; called by muse, mutect2, varscan2
- PCNX3 | c.5275C>T p.Q1759* | Nonsense Mutation (SNP) | VAF 97/206 reads (47%) | catalogued as COSV63136354; called by muse, mutect2, varscan2
- PDE5A | c.2509G>C p.E837Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); catalogued as COSV53347088, COSV53347671; called by muse, mutect2, varscan2
- PER1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV57919051; called by muse, mutect2, varscan2
- PKP3 | c.1468C>A p.Q490K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV58985929, COSV58986895; called by muse, mutect2, varscan2
- PLEC | c.11704G>A p.E3902K (on ENST00000322810 / NM_201380.4; = p.E3792K on NM_000445.5) | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV59629506; called by muse, mutect2, varscan2
- PLEC | c.11265G>A p.M3755I (on ENST00000322810 / NM_201380.4; = p.M3645I on NM_000445.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV59629569; called by muse, mutect2, varscan2
- POGZ | c.2321C>G p.S774C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55034838; called by muse, varscan2
- PPP2R5D | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.956); catalogued as COSV57839834; called by muse, mutect2, varscan2
- PURG | c.442A>T p.R148W | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV53299271, COSV99988722; called by muse, mutect2, varscan2
- QRICH2 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 145/178 reads (81%) | catalogued as COSV99428747; called by muse, mutect2, varscan2
- SCAI | c.1384C>G p.P462A (on ENST00000336505 / NM_001144877.3; = p.P485A on NM_173690.5) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60612273; called by muse, mutect2, varscan2
- SERPINA3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV67585986; called by muse, mutect2, varscan2
- SIDT2 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99637057; called by muse, varscan2
- SIN3A | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.775); catalogued as rs894918712, COSV64585040; called by muse, varscan2
- SNRPD2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV50003754; called by muse, mutect2, varscan2
- SORBS1 | c.3709C>G p.Q1237E (on ENST00000361941 / NM_001034954.2; = p.Q629E on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53354706, COSV99527334; called by muse, mutect2, varscan2
- SPG7 | c.1309G>A p.G437S (on ENST00000268704; = p.G444S on NM_003119.4) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV99244501; called by muse, mutect2, varscan2
- ST6GAL1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 24/49 reads (49%) | PolyPhen benign (0.01); catalogued as rs1460870059, COSV51469042, COSV51474048; called by muse, mutect2, varscan2
- SULF1 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.138); catalogued as COSV52679778; called by muse, mutect2, varscan2
- SYT4 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54899337, COSV54899899; called by muse, mutect2, varscan2
- TBXT | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51617495; called by muse, mutect2, varscan2
- TCTE1 | c.1269C>G p.I423M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs1561922071, COSV65255443; called by muse, mutect2, varscan2
- TROAP | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57743825; called by muse, mutect2, varscan2
- TRRAP | c.6448G>A p.D2150N (on ENST00000359863 / NM_001244580.1; = p.D2132N on NM_003496.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs746396500, COSV62843220; called by muse, mutect2, varscan2
- TXNDC16 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767690238, COSV55984394; called by muse, mutect2, varscan2
- WDPCP | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV55418380; called by muse, mutect2, varscan2
- ZNF3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.13); catalogued as COSV52795667; called by muse, mutect2, varscan2
- ZNF492 | c.1288T>A p.F430I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV71761899; called by muse, mutect2, varscan2
- ZNF568 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61740278, COSV61741306; called by muse, mutect2, varscan2
- ZNF629 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs1175782163, COSV52698233; called by muse, mutect2, varscan2
- ZNF653 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV99542082; called by muse, mutect2
- ZWILCH | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57179517; called by muse, mutect2
- ITPR2 | c.1564C>A p.L522I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); called by muse, mutect2
- KANSL3 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- LDHC | c.281del p.V94Afs*23 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- RCC1L | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 161/396 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADGRE2 | c.1401C>T p.F467= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV59693138; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1689G>A p.K563= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV52872702; called by muse, mutect2
- CCDC65 | c.690C>T p.L230= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV56739457; called by muse, mutect2, varscan2
- CCDC88B | c.1677G>A p.E559= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV57265856; called by muse, mutect2, varscan2
- CECR2 | c.315C>T p.F105= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV52840066; called by muse, mutect2, varscan2
- CHST8 | c.105G>A p.T35= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs143467252; called by muse, mutect2, varscan2
- CLCN1 | c.370C>T p.L124= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs1186091792, COSV58369398; called by muse, mutect2, varscan2
- CNGA1 | c.1560C>T p.L520= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs775781523, COSV62054060; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.3897A>G p.L1299= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1399431940, COSV66414031; called by muse, mutect2
- COL9A3 | c.666G>A p.P222= | Silent (SNP) | VAF 51/106 reads (48%) | catalogued as rs773420523, COSV59652209; called by muse, mutect2, varscan2
- CPSF4 | c.120C>T p.V40= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs772613412, COSV52857317; called by muse, mutect2, varscan2
- CSPG4 | c.282G>A p.L94= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV57894102; called by muse, mutect2, varscan2
- DISP2 | c.1299C>G p.L433= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV51119949; called by muse, mutect2, varscan2
- DISP2 | c.2445C>G p.L815= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV51119983; called by muse, mutect2, varscan2
- DNM1L | c.507C>T p.L169= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV56773880; called by muse, mutect2, varscan2
- ENPP3 | c.699C>G p.L233= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV62954022; called by muse, mutect2, varscan2
- ETV3L | c.720G>T p.L240= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV71901037; called by muse, mutect2, varscan2
- FUZ | c.402C>T p.L134= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV58241291; called by muse, varscan2
- GAREM1 | c.1074G>A p.K358= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV52508522; called by muse, mutect2, varscan2
- GPR179 | c.2655G>C p.R885= (on ENST00000621958; = p.R884= on NM_001004334.4) | Silent (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.588C>T p.L196= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1232076022, COSV52372901; called by muse, mutect2, varscan2
- KIR3DL1 | c.51G>A p.Q17= | Silent (SNP) | VAF 79/226 reads (35%) | catalogued as COSV58490105; called by muse, mutect2, varscan2
- LAP3 | c.477C>T p.L159= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV56899594; called by muse, mutect2, varscan2
- LBH | c.99C>T p.L33= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs1483237262, COSV68049295, COSV68049310; called by muse, mutect2, varscan2
- LGI2 | c.738C>T p.I246= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs757666849, COSV66122856, COSV66123798; called by muse, mutect2, varscan2
- MIF4GD | c.426G>A p.L142= (on ENST00000325102 / NM_001370592.1; = p.L176= on NM_020679.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/253 reads (8%) | catalogued as COSV99821437; called by muse, mutect2
- NBAS | c.6186G>A p.L2062= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV55719506; called by muse, mutect2, varscan2
- NELL2 | c.2388C>T p.L796= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV61573509; called by muse, mutect2, varscan2
- NXPH3 | c.438C>T p.I146= | Silent (SNP) | VAF 54/94 reads (57%) | catalogued as COSV60872140; called by muse, mutect2, varscan2
- OLFML2A | c.375C>T p.L125= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV59160946; called by muse, mutect2, varscan2
- PCDHGA8 | c.2175C>T p.L725= | Silent (SNP) | VAF 50/63 reads (79%) | catalogued as COSV53935230, COSV54067835; called by muse, mutect2, varscan2
- PRDM2 | c.2541C>G p.V847= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV52445738; called by muse, mutect2, varscan2
- PRKDC | c.5442C>T p.F1814= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV58049486; called by muse, mutect2, varscan2
- PRKG2 | c.1731G>A p.L577= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV52323312; called by muse, mutect2, varscan2
- RAB33A | c.81G>T p.S27= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV57061616; called by muse, mutect2, varscan2
- RAB33A | c.231C>T p.T77= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV57061627; called by muse, mutect2, varscan2
- RHOD | c.507C>T p.L169= | Silent (SNP) | VAF 55/219 reads (25%) | catalogued as COSV58211332; called by muse, mutect2, varscan2
- SHC2 | c.1467C>T p.H489= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as rs375069437, COSV99198898; called by muse, mutect2, varscan2
- SHOX2 | c.504C>T p.F168= (on ENST00000441443 / NM_006884.3; = p.F192= on NM_003030.4) | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV101273734; called by muse, mutect2, varscan2
- SLC22A6 | c.90G>A p.L30= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV64560119; called by muse, mutect2, varscan2
- TARS3 | c.1998G>A p.V666= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV60107950; called by muse, mutect2, varscan2
- TBC1D10A | c.123C>T p.L41= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs775782497, COSV53164008; called by muse, mutect2, varscan2
- THPO | c.996G>C p.L332= (on ENST00000649095 / NM_001290003.1; = p.L192= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV52615581; called by muse, mutect2, varscan2
- TRBC2 | c.168C>T p.V56= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs782666866; called by muse, mutect2, varscan2
- TSC2 | c.936C>T p.L312= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV54762732; called by muse, mutect2, varscan2
- TTC17 | c.2070G>A p.L690= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99234600; called by muse, varscan2
- TTN | c.43863G>A p.V14621= (on ENST00000591111; = p.V7197= on NM_003319.4) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV60010688; called by muse, mutect2, varscan2
- WBP4 | c.156G>A p.L52= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs758942737, COSV65273848; called by muse, mutect2, varscan2
- ZFHX4 | c.7860C>G p.L2620= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV50715317; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498923 G>A | 5'Flank (SNP) | VAF 5/15 reads (33%) | catalogued as rs1346377193; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499098 G>C | 5'Flank (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- AP000769.5 | chr11:65499479 G>C | 5'Flank (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.718-992G>A | Intron (SNP) | VAF 43/95 reads (45%) | catalogued as rs1179061113, COSV62262842; called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630552 C>T | 5'Flank (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2
- GNA12 | c.526-29317G>A | Intron (SNP) | VAF 19/50 reads (38%) | catalogued as rs1216062425, COSV51740316; called by muse, mutect2, varscan2
- OBSCN | c.4585+2679G>C | Intron (SNP) | VAF 44/144 reads (31%) | catalogued as COSV52767970; called by muse, mutect2, varscan2
- PLEKHG5 | c.-31G>C | 5'UTR (SNP) | VAF 22/70 reads (31%) | catalogued as COSV66661276; called by muse, mutect2, varscan2
- ZNF137P | n.1702C>T | RNA (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
